Somatic mutation profile of tumor specimen TCGA-HC-7080-01A (aliquot TCGA-HC-7080-01A-11D-1961-08) from TCGA case TCGA-HC-7080, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 66.4 years (24,243 days).
Specimen TCGA-HC-7080-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bf4b77dd-4247-4545-a2ce-50fff37fcfca.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HC-7080-10A (Blood Derived Normal), aliquot TCGA-HC-7080-10A-01D-1961-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bebf0e96-5f81-4cf3-b147-a5d6de7356ce

The open-access MAF lists 28 somatic variants for this specimen: 21 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 16, Silent 7, Frame Shift Del 1, Nonsense Mutation 1, In Frame Del 1, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GALNS | c.463G>A p.G155R | Missense Mutation (SNP) | VAF 56/129 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs398123438, CM970584, COSV51938777, COSV99243197; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SPOP | c.392G>C p.W131S | Missense Mutation (SNP) | VAF 86/206 reads (42%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as rs1057519969, COSV61653907, COSV61656320; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AFF3 | c.2467T>C p.C823R | Missense Mutation (SNP) | VAF 71/179 reads (40%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.602); catalogued as COSV57861533; called by muse, mutect2, varscan2
- AHCY | c.760A>G p.M254V | Missense Mutation (SNP) | VAF 102/223 reads (46%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.487); catalogued as rs1329329628, COSV54153722; called by muse, mutect2, varscan2
- BBX | c.1024A>G p.M342V | Missense Mutation (SNP) | VAF 90/201 reads (45%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV57888748; called by muse, mutect2, varscan2
- CACNA1E | c.6484G>A p.V2162I (on ENST00000367573 / NM_001205293.3; = p.V2119I on NM_000721.4) | Missense Mutation (SNP) | VAF 56/79 reads (71%) | SIFT deleterious (0.02); PolyPhen benign (0.164); catalogued as rs373618053; called by muse, mutect2, varscan2
- CAGE1 | c.1268G>A p.R423K (on ENST00000512086; = p.R287K on NM_205864.3) | Missense Mutation (SNP) | VAF 44/97 reads (45%) | SIFT tolerated (0.24); PolyPhen benign (0.047); catalogued as COSV57079050; called by muse, mutect2, varscan2
- CD101 | c.49C>T p.L17F | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.066); catalogued as COSV56719166; called by muse, mutect2, varscan2
- CPNE3 | c.476C>A p.S159* | Nonsense Mutation (SNP) | VAF 30/81 reads (37%) | catalogued as COSV52207935; called by muse, mutect2, varscan2
- FAM83E | c.759C>T p.S253= | Splice Region (SNP) | VAF 30/71 reads (42%) | catalogued as rs762595974, COSV52377232; called by muse, mutect2, varscan2
- IRX6 | c.1232G>T p.G411V | Missense Mutation (SNP) | VAF 52/134 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV51861231; called by muse, mutect2, varscan2
- KLK4 | c.101G>A p.G34D | Missense Mutation (SNP) | VAF 180/384 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1243637967, COSV60676666; called by muse, mutect2, varscan2
- LRRFIP1 | c.1607G>A p.S536N (on ENST00000392000 / NM_001137552.2; = p.S512N on NM_004735.4) | Missense Mutation (SNP) | VAF 62/142 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.055); catalogued as COSV55249809; called by muse, mutect2, varscan2
- LTF | c.996G>T p.R332S | Missense Mutation (SNP) | VAF 34/61 reads (56%) | SIFT tolerated (0.2); PolyPhen benign (0.354); catalogued as COSV51609941; called by muse, mutect2, varscan2
- PCDHA9 | c.1612C>T p.R538C | Missense Mutation (SNP) | VAF 122/277 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.082); catalogued as rs782219075, COSV65329183; called by muse, mutect2, varscan2
- PPRC1 | c.3902G>A p.R1301Q | Missense Mutation (SNP) | VAF 38/75 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.743); catalogued as rs746405708, COSV53386941; called by muse, mutect2, varscan2
- U2AF1L4 | c.553C>T p.L185F (on ENST00000412391; = p.S126= on NM_144987.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as COSV53075701; called by muse, mutect2, varscan2
- UNC5B | c.758C>T p.A253V | Missense Mutation (SNP) | VAF 47/122 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.111); catalogued as COSV58978612; called by muse, mutect2, varscan2
- CLEC16A | c.963_965del p.F321del | In Frame Del (DEL) | VAF 14/50 reads (28%) | called by pindel, varscan2
- SSB | c.976del p.L326* | Frame Shift Del (DEL) | VAF 21/37 reads (57%) | called by mutect2, pindel, varscan2
- XRCC6 | c.122dup p.L41Ffs*3 | Frame Shift Ins (INS) | VAF 30/64 reads (47%) | called by mutect2, varscan2
- AHNAK2 | c.411C>T p.F137= | Silent (SNP) | VAF 28/106 reads (26%) | catalogued as rs758856637, COSV60921529; called by muse, varscan2
- KLK5 | c.123C>T p.T41= | Silent (SNP) | VAF 21/45 reads (47%) | catalogued as COSV60450871; called by muse, mutect2, varscan2
- LCN9 | c.507G>A p.P169= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as rs781706474, COSV52991600; called by muse, mutect2, varscan2
- MCF2L | c.1818G>A p.R606= (on ENST00000375608; = p.R574= on NM_024979.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as COSV65051792; called by muse, mutect2, varscan2
- PHLDB1 | c.3405C>T p.D1135= | Silent (SNP) | VAF 34/90 reads (38%) | catalogued as rs1565486938, COSV61880213; called by muse, mutect2, varscan2
- SF3B1 | c.1740G>A p.P580= | Silent (SNP) | VAF 34/76 reads (45%) | catalogued as rs566175207, COSV59219929; called by muse, mutect2, varscan2
- WNT7A | c.324C>T p.Y108= | Silent (SNP) | VAF 58/133 reads (44%) | catalogued as rs773384342, COSV53200432; called by muse, varscan2
